Surgical pathology report (de-identified scan), TCGA case TCGA-66-2767, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Indivumed, specimen TCGA-66-2767-01A (Primary Tumor).

[page 1 of 2]
Material examined:

Right lung, among others

Clinical diagnosis and question

Right central squamous cell carcinoma with status post pneumonia / pleuritis 05/07. Suspected occupational exposure to asbestos.

REPORT ON FINDINGS**Macroscopy**

- 1.) Inflated, fixed right lung measuring 12 x 11 cm at the base and up to 25 cm in length, central bronchus resection plane located 1.2 cm proximal to the bifurcation of the upper lobe bronchus. Upper pleural fissure extensively obliterated in dorsal third, over segment 6 and adjacent sections of S2 an 8.5 x 6 cm area of parietal pleura is extensively adhesive. At the hilus are six partly lesioned mobile grayish-black nodes between 1.1 and 2 cm in size, lower lobe bronchus and proximal sections of lower lobe segmental bronchi largely obstructed by a central moderately solid, pale brownish, predominantly endobronchial tumor, max. 4.8 cm in size, in the lower lobe. Involvement of several grayish-black pigmented nodes up to 1.4 cm in size by the tumor. Central blood vessels partly narrowed by the tumor. Tumor spread across the pleural fissure questionably into the upper lobe. Sleeve-like spread along the lower lobe bronchus, with apparent involvement of a 2.2 cm grayish-black node extending right up to the hilar resection surface. Intermediate and peripheral lower lobe bronchial branches are markedly dilated and filled with thick mucus. Parenchyma in segment 6 below the pleural adhesion is an indurated and pale brownish-yellow area of about 3.5 cm with unclear demarcation, medial parenchyma in segment 3 and apical parenchyma in segment 1 rarefied with lacunae or lacuna systems of up to 0.5 cm. Pleura over segment 1 shows whitish discoloration in several, partly striated areas of up to 5 cm, underlying parenchyma here shows an indurated and grayish-white seam about 0.3 cm thick.
- 2.) Hilar LN (station 10) right: 2.6 cm lesioned node or node part, section surfaces predominantly pale brown to whitish suggestive of a tumor.
- 3.) Pulmonary ligament LN (station 9) right: two lesioned grayish-black nodes with some surrounding tissue, 0.3 and 1.2 cm in size.
- 4.) Paraesophageal LN (station 8) right: five lesioned grayish-black nodes or node parts between 0.3 and 1.2 cm.
- 5.) Subcarinal LN (station 7): 2 cm node part with pale brown to whitish section surfaces suggestive of a tumor.
- 6.) Low paratracheal LN (station 4) right: 3.5 cm lesioned node with predominantly pale brown to whitish section surfaces suggestive of a tumor.
- 7.) Retrotracheal right: 1 cm lesioned grayish-black node with some surrounding tissue.
- 8.) High paratracheal LN (station 2) right: five lesioned grayish-brown nodes or node parts between 0.1 and 1 cm.
- 9.) Hilar LN (station (St.10) left: 2.5 cm lesioned node or node part, section surfaces pale brown to whitish suggestive of a tumor.
- 10.) Low paratracheal LN (station 4) left: 1.5 cm five lesioned grayish-brown node with some surrounding tissue.
- 11.) High paratracheal LN (station 2) left: 1.1 cm lesioned grayish-brown node with some surrounding tissue, section surfaces pale brown to whitish .

[page 2 of 2]
Examined:

1.) Tumor with rest of parenchyma + proximal branch of B10, 2 sections of tumor with lower lobe bronchus + involved nodes, 2 sections with pleural fissure to upper lobe (upper lobe portion partly color-marked), 2 sections main bronchus at bifurcation of lower lobe bronchus with node close to hilus (hilar resection surface color-marked), S10 intermediate, S6 at junction of S2, S1 apical, S3 medial, S2 dorsal, central bronchus resection plane + resection margins of vessels, hilar nodes, 5.), 6.) 1 section each, 9.) 2 sections, 4.), 7.), 8.), 10.) and 11.) All material (in 10. and 11. halved in each case), 23 blocks, partly Elastica-van Gieson, PAS, diastase-PAS, iron staining.

Microscopy

Description of histological and cytological findings omitted for capacity reasons.

EVALUATION

Primary diagnosis/diagnoses:

Central bronchopulmonary, histologically poorly to moderately differentiated, partly keratinizing squamous cell carcinoma of the lower lobe of the right lung with marked lymphogenic metastasization. TNM classification according to this picture pT2 pN3 V1 R0, stage IIIB. C 34.3; M 8070/3. G3.

Secondary diagnosis/diagnoses:

Largely organized pneumonic infiltrate with fibrous parenchymal remodeling in S6 and old thromboses of adjacent small pulmonary arteries. Flat subpleural parenchymal scar in apical S1 with slight perifocal emphysema. Circumscribed high-grade emphysematous stromal remodeling with formation of small cysts in segments 1 and 3. Minimal mixed dust deposits in lung parenchyma and accumulation of alveolar siderophages with possible respiratory bronchiolitis. Pleural fibrosis especially over the fibrous remodeling area in S6 with adhesion. Tumor-free lymph nodes with slight to moderate pigment deposits and in some cases reactive follicular hyperplasia.

Remark/addendum:

On the one hand, the carcinoma is spreading to central segmental bronchi of the lower lobe by completely infiltrating and obliterating these, while growing into the lower lobe bronchus. On the other hand, the tumor extends to the pleura fissure. The angioinvasion does not affect small arteries and veins in the tumor area. Most of the 30 lymph nodes found are infiltrated with metastases, and they are not only detected in the tumor area and the hilus region, while the lymph node metastasis the near the main bronchus extends to within 0.5 mm of the mediastinal resection surface, but they are also found in the lymph node areas registered under 2.), 5.), 6.) and 8.) - 11.).

Source: NCI Genomic Data Commons file a91de5b1-13d9-4717-a88e-3c866a682866 (TCGA-66-2767.BC27C9EE-26E1-4362-B03D-4E2C08ED6111.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).